Gene-level copy-number profile of tumor specimen TCGA-CV-7238-01A from TCGA case TCGA-CV-7238, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.7 years (25,471 days).
Specimen TCGA-CV-7238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e86db3ad-48d4-47e0-90fd-3478dba87d95.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7238-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/79224256-c634-4b13-96f3-21c3af0b0a53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,355; copy number 2: 50,067; copy number 3: 6,173; copy number 4: 128; copy number 7: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7238-01A-11D-2010-01): tumor purity 0.25, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 92 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:34,610,486–36,163,913, 92 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,355. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
